Gene-level copy-number profile of tumor specimen C3N-04113-03 from CPTAC case C3N-04113, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 31.0 years (11,338 days).
Specimen C3N-04113-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Frontal Lobe; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file ca7b684b-0f76-423e-82fb-aa5beeee3b51.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-04113-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,719 have no estimate.
https://portal.gdc.cancer.gov/files/2cea6bb2-eca8-460a-9691-db30e1fabf55

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 561; copy number 1: 1,162; copy number 2: 7,198; copy number 3: 41,151; copy number 4: 3,280; copy number 5: 2,805; copy number 6: 2,333; copy number 7: 300; copy number 8: 90; copy number 9: 15; copy number 11: 9.

Homozygous deletions (total copy number 0; autosomes only): 51 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:170,615,515–170,738,536, 1 gene (within-gene range 0–3): AL672310.1.
- chr6:170,736,173–170,737,777, 1 gene: AL731684.1.
- chr9:42,183,659–42,189,887, 1 gene: SPATA31A6.
- chr9:42,231,811–42,499,134, 6 genes: AL445584.2, FKBP4P6, SDR42E1P2, ATP5F1AP1, RAB28P3, RBPJP6.
- chr9:61,581,813–61,642,494, 3 genes: AL935212.3, FAM242D, Y_RNA.
- chr15:100,602,589–100,828,497, 5 genes (within-gene range 0–3): ASB7, Y_RNA, AC090695.1, AC087762.1, AC087762.2.
- chr15:101,289,784–101,525,202, 1 gene (within-gene range 0–2): PCSK6.
- chr15:101,334,437–101,979,093, 30 genes (within-gene range 0–2): PCSK6-AS1, AC090164.2, AC090164.3, AC090164.4, SNRPCP18, AC090164.1, LINC02348, TM2D3, RNU6-807P, TARS3, AC027559.1, DNM1P47, GOLGA8VP, RN7SL209P, OR4F6, OR4F15, OR4F14P, OR4F13P, OR4F28P, WBP1LP5, AC140725.2, OR4F4, OR4G2P, OR4G6P, FAM138E, AC140725.1, MIR1302-10, WASH3P, MIR6859-3, DDX11L9.
- chr21:44,107,373–44,210,114, 3 genes (within-gene range 0–2): PWP2, GATD3A, LINC01678.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 414 genes in 18 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:25,242,249–25,338,213, 1 gene, copy number 7 (within-gene range 3–7): RSRP1.
- chr1:25,272,393–25,330,445, 2 genes, copy number 7: RHD, SDHDP6.
- chr1:248,590,487–248,645,278, 5 genes, copy number 8: OR2T10, Y_RNA, AC098483.2, OR2T11, OR2T35.
- chr4:132,836,772–132,988,677, 2 genes, copy number 7: AC115622.1, AC110751.1.
- chr7:52,891,837–56,882,146, 99 genes, copy number 7–8 (broad region; genes not listed).
- chr8:12,115,767–12,177,550, 5 genes, copy number 7 (within-gene range 4–7): FAM66D, AC130366.1, USP17L7, USP17L2, DEFB109D.
- chr11:18,933,813–18,939,721, 2 genes, copy number 8: MRGPRX1, AC023078.1.
- chr15:67,063,763–69,272,217, 39 genes, copy number 7 (within-gene range 6–7): SMAD3, AC012568.1, AAGAB, RPS24P16, IQCH, IQCH-AS1, C15orf61, AC016355.1, MAP2K5, HNRNPA1P5, SKOR1, AC009292.2, AC009292.1, RNU6-1, AC022254.1, AC135628.1, PIAS1, AC107871.1, CALML4, CLN6, HMGN2P40, AC107871.2, FEM1B, ITGA11, CORO2B, CARS1P1, ANP32A, MIR4312, SPESP1, AC087639.1, AC087639.2, AC027088.1, NOX5, AC027088.5, AC027088.4, AC027088.3, EWSAT1, AC027088.2, GLCE.
- chr15:74,461,265–77,485,607, 108 genes, copy number 7 (broad region; genes not listed).
- chr15:82,925,884–87,047,303, 105 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr15:93,230,034–93,569,483, 5 genes, copy number 7: AC091078.1, AC112693.1, AC112693.2, AC091078.2, SEPHS1P2.
- chr15:95,186,634–95,327,129, 4 genes, copy number 7: LINC01197, AC104260.1, AC104260.2, AC104260.3.
- chr15:97,876,289–98,293,199, 10 genes, copy number 7: AC024651.2, ARRDC4, AC024651.1, LINC02251, AC022523.1, RNU6-1186P, LINC01582, AC022523.3, AC022523.2, AC015722.1.
- chr16:55,760,566–55,793,960, 1 gene, copy number 7: CES1P1.
- chr17:51,153,559–51,162,428, 1 gene, copy number 7 (within-gene range 3–7): NME1.
- chr18:45,034–268,050, 9 genes, copy number 11: AP001005.1, TUBB8B, AP001005.3, IL9RP4, AP001005.2, ROCK1P1, MIR8078, USP14, THOC1.
- chr18:4,459,230–5,385,330, 15 genes, copy number 9: ELOCP27, AP005203.1, PPIAP14, LINC01892, BOD1P2, AKAIN1, AP005380.1, AP001496.4, AP001496.2, LINC00526, LINC00667, AP001496.3, ZBTB14, AP001496.1, AP005671.1.
- chr18:36,108,531–36,129,385, 1 gene, copy number 8: SLC39A6.

Autosomal genes at a single copy (total copy number 1): 1,124. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
